Somatic mutation profile of tumor specimen TCGA-78-7152-01A (aliquot TCGA-78-7152-01A-11D-2036-08) from TCGA case TCGA-78-7152, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.1 years (23,782 days).
Specimen TCGA-78-7152-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f160b20c-f7d3-406e-90e0-2406cb7ab41d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7152-10A (Blood Derived Normal), aliquot TCGA-78-7152-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c53f2c29-fa87-40cd-a7b8-da1ea85523c5

The open-access MAF lists 216 somatic variants for this specimen: 160 protein-altering or splice-affecting, 47 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 47, Nonsense Mutation 10, Frame Shift Ins 5, RNA 5, Frame Shift Del 5, Splice Site 2, Intron 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 17/37 reads (46%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.200G>T p.R67L (on ENST00000297504 / NM_001282291.2; = p.R50L on NM_007188.5) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as COSV52503408, COSV52505170; called by muse, mutect2, varscan2
- ACOX3 | c.904G>T p.G302W | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62712226; called by muse, mutect2, varscan2
- ACTN3 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as rs1354966216, COSV101557904, COSV72207607; called by muse, mutect2, varscan2
- ADAM22 | c.1296_1297insCA p.C433Hfs*48 | Frame Shift Ins (INS) | VAF 31/139 reads (22%) | catalogued as COSV99715815; called by mutect2, pindel, varscan2
- ADCY1 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV52029792, COSV52033448; called by muse, mutect2, varscan2
- ADGRG2 | c.1939C>G p.L647V (on ENST00000379869 / NM_001079858.3; = p.L644V on NM_005756.4) | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV61339347; called by muse, mutect2
- ADGRL3 | c.833G>T p.G278V (on ENST00000506720 / NM_001322402.2; = p.G210V on NM_015236.6) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72268794; called by muse, mutect2, varscan2
- ADGRV1 | c.9526G>T p.G3176* | Nonsense Mutation (SNP) | VAF 6/114 reads (5%) | catalogued as COSV67986315; called by muse, mutect2
- AHCYL1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs750092870, COSV63208745; called by muse, mutect2, varscan2
- AKAP8L | c.1110G>C p.K370N | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV68473272, COSV68473578; called by muse, mutect2
- AMOTL2 | c.593_594insT p.A201Cfs*2 | Frame Shift Ins (INS) | VAF 24/80 reads (30%) | catalogued as COSV99998026, COSV99998437; called by mutect2, pindel, varscan2
- AOAH | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV51742188; called by muse, mutect2
- APBA1 | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55228928; called by muse, mutect2, varscan2
- ARL6IP6 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV58442922; called by muse, mutect2, varscan2
- ATAD3B | c.206-2A>T p.X69_splice | Splice Site (SNP) | VAF 11/20 reads (55%) | catalogued as COSV58021007; called by muse, mutect2, varscan2
- ATF7IP | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV53771644, COSV99661271; called by muse, mutect2, varscan2
- ATP6V1C1 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV67778095; called by muse, mutect2, varscan2
- BCO2 | c.1409A>G p.Y470C | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374509038; called by muse, mutect2, varscan2
- BEGAIN | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as COSV62068908; called by muse, mutect2, varscan2
- BIRC6 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.077); catalogued as COSV101427860; called by muse, mutect2, varscan2
- BMPR1B | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV52778068; called by muse, mutect2, varscan2
- C17orf58 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV57816949; called by muse, mutect2, varscan2
- C5 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as rs1274387991, COSV56327921; called by muse, mutect2
- C6orf47 | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.666); catalogued as COSV63263816; called by muse, mutect2, varscan2
- CACNA1C | c.2683C>A p.R895S | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV59724448, COSV59754616; called by muse, mutect2, varscan2
- CCT2 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV54740321; called by muse, mutect2, varscan2
- CD47 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62527250; called by muse, mutect2
- CDH2 | c.2464G>T p.V822F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.322); catalogued as COSV52281749; called by muse, mutect2
- CEACAM5 | c.1430G>T p.C477F | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV55752416; called by muse, mutect2, varscan2
- CEBPE | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.447); catalogued as COSV52830880, COSV99247345; called by muse, mutect2, varscan2
- CEP350 | c.3833C>G p.S1278C | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV62603370, COSV62610858; called by muse, mutect2
- CEP89 | c.2206C>T p.L736F | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59864669; called by muse, mutect2, varscan2
- CHD4 | c.3443A>G p.H1148R (on ENST00000357008 / NM_001363606.2; = p.H1161R on NM_001273.5) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58902003; called by muse, mutect2, varscan2
- CHRNB2 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100872525, COSV63808275, COSV63808363; called by muse, mutect2
- CRIM1 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.483); catalogued as rs199612229; called by muse, mutect2, varscan2
- CTNNA2 | c.1075G>T p.G359* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as COSV58151365, COSV58154909; called by muse, mutect2, varscan2
- CWH43 | c.526A>G p.K176E | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV56939357; called by muse, mutect2, varscan2
- DDX23 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as COSV57283969; called by muse, mutect2, varscan2
- DIP2C | c.3518C>G p.S1173C | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV104384097, COSV55160024; called by muse, mutect2
- DOCK9 | c.3817A>G p.N1273D (on ENST00000376460 / NM_001366676.2; = p.N1274D on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.283); catalogued as COSV59631307; called by muse, mutect2, varscan2
- DSG1 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.028); catalogued as COSV57134499, COSV99936140; called by muse, mutect2, varscan2
- EFL1 | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51606011; called by muse, mutect2
- FAM83B | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV60922522; called by muse, mutect2, varscan2
- FAT2 | c.12557C>A p.S4186Y | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.107); catalogued as COSV55820667; called by muse, mutect2, varscan2
- FCGRT | c.680A>G p.Y227C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54542198; called by muse, mutect2, varscan2
- FNBP4 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55448946; called by muse, mutect2, varscan2
- FRG2B | c.51C>G p.C17W | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as COSV71043089; called by muse, mutect2
- FRG2C | c.51C>G p.C17W | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as COSV57314975; called by muse, mutect2
- FZD10 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs374628122, COSV57473814, COSV99969522; called by muse, mutect2, varscan2
- GCSAML | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.316); catalogued as COSV63578023; called by muse, mutect2
- GP6 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1394760885, COSV59977729; called by muse, mutect2, varscan2
- GPR75 | c.1487G>T p.S496I | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100765900; called by muse, mutect2, varscan2
- GREM1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV55715130; called by muse, mutect2, varscan2
- H2BC3 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as COSV63551027; called by muse, mutect2, varscan2
- HAUS4 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.84); catalogued as COSV52827460; called by muse, mutect2, varscan2
- IGKV1-6 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 80/267 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs1558583684; called by muse, mutect2, varscan2
- IL6 | c.10T>G p.F4V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs958965295, COSV51732853; called by muse, mutect2, varscan2
- INPP4B | c.2419G>T p.E807* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV53727473; called by muse, mutect2, varscan2
- ITK | c.1523T>A p.L508Q | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV70062634; called by muse, mutect2, varscan2
- KIFC1 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as COSV65737597; called by muse, mutect2
- KIFC1 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV65729269; called by muse, mutect2, varscan2
- KITLG | c.303del p.I101Mfs*5 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | catalogued as CX1511918; called by mutect2, pindel, varscan2
- KLK8 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV51592197; called by muse, mutect2, varscan2
- KMT2D | c.7982T>A p.L2661H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99977782; called by muse, mutect2, varscan2
- KRTAP6-3 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 14/108 reads (13%) | PolyPhen possibly damaging (0.728); catalogued as COSV101196467; called by muse, mutect2, varscan2
- LBP | c.1034C>G p.S345C | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV54140644; called by muse, varscan2
- LRFN5 | c.1888C>A p.P630T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV53258599, COSV53278115; called by muse, mutect2, varscan2
- LRRC7 | c.1645G>T p.D549Y (on ENST00000651989 / NM_001370785.2; = p.D516Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV50468366; called by muse, mutect2, varscan2
- LUM | c.260A>T p.E87V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV57128284; called by muse, mutect2, varscan2
- MAP3K6 | c.1848C>G p.I616M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV62888677; called by muse, mutect2, varscan2
- MEGF10 | c.1875C>A p.S625R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV57249930; called by muse, mutect2, varscan2
- MFAP4 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs367629703, COSV55191002; called by mutect2, varscan2
- MIER3 | c.1112C>T p.S371L (on ENST00000381199 / NM_001297599.2; = p.S370L on NM_152622.4) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.193); catalogued as COSV67082856; called by muse, mutect2, varscan2
- MIP | c.118C>A p.H40N | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV57788468; called by muse, mutect2, varscan2
- MKNK1 | c.772G>T p.V258F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57861422; called by muse, mutect2, varscan2
- MUC16 | c.37385A>G p.H12462R | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs747378930, COSV67469457; called by muse, mutect2, varscan2
- MUC16 | c.18266C>G p.S6089* | Nonsense Mutation (SNP) | VAF 5/73 reads (7%) | catalogued as COSV67468042, COSV67469467; called by muse, mutect2
- MYH7 | c.2625G>C p.E875D | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV62517757; called by muse, mutect2, varscan2
- MYH8 | c.2465G>T p.R822L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV67965950; called by muse, mutect2, varscan2
- MYO16 | c.268G>T p.V90F | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV51797182; called by muse, mutect2, varscan2
- MYO16 | c.1685G>A p.C562Y | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51785249; called by muse, mutect2, varscan2
- NCKAP5 | c.4370C>A p.T1457N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); catalogued as COSV58446589; called by muse, mutect2, varscan2
- NELL1 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.09); catalogued as COSV54270442; called by muse, mutect2, varscan2
- NIPBL | c.7906G>A p.E2636K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV56952609; called by muse, mutect2, varscan2
- NPRL3 | c.1265G>C p.R422P (on ENST00000611875 / NM_001077350.3; = p.R397P on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54738480; called by muse, mutect2
- NT5C1B | c.1114G>C p.D372H (on ENST00000359846 / NM_001199086.2; = p.D312H on NM_033253.4) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV58396247; called by muse, mutect2, varscan2
- OR2M5 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1320736496, COSV63546353; called by muse, mutect2, varscan2
- OR4S2 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56747081; called by muse, mutect2, varscan2
- OR52B4 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68769010; called by muse, mutect2, varscan2
- OR5F1 | c.329C>A p.T110N | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV53546722; called by muse, mutect2, varscan2
- OR6Q1 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV56933230; called by muse, mutect2, varscan2
- OR8K1 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV54402561, COSV54402755; called by muse, mutect2
- PBX1 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV63344077; called by muse, mutect2, varscan2
- PCSK7 | c.989G>C p.G330A | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58007483; called by muse, mutect2, varscan2
- PEX26 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs754375470, COSV61604525; called by muse, mutect2, varscan2
- PGBD1 | c.1116G>C p.E372D | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52553690; called by muse, mutect2, varscan2
- PLEC | c.11563G>T p.E3855* (on ENST00000322810 / NM_201380.4; = p.E3745* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as COSV59641689, COSV59705192; called by muse, mutect2, varscan2
- POLR1G | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56234644; called by muse, mutect2, varscan2
- POLR3B | c.567C>G p.I189M | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.633); catalogued as COSV57279628; called by muse, mutect2, varscan2
- PPP4R4 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58555035; called by muse, mutect2, varscan2
- PREPL | c.1658C>A p.T553K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53216958; called by muse, mutect2, varscan2
- PRKCE | c.1346A>T p.D449V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60319606; called by muse, mutect2, varscan2
- PRRC2B | c.2659G>C p.E887Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV61937640; called by muse, mutect2, varscan2
- PSMD3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV52857794, COSV52859346; called by muse, mutect2
- PSME4 | c.4636G>A p.D1546N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV101122249; called by muse, mutect2, varscan2
- PUM2 | c.2485-1G>A p.X829_splice | Splice Site (SNP) | VAF 14/70 reads (20%) | catalogued as COSV57581113; called by muse, mutect2, varscan2
- PURG | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53300843; called by muse, mutect2
- RABEP2 | c.1445G>T p.C482F | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV62869657; called by muse, mutect2, varscan2
- RABGAP1L | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99267954; called by muse, mutect2
- RTL9 | c.1793C>G p.S598* | Nonsense Mutation (SNP) | VAF 32/65 reads (49%) | catalogued as COSV71825670; called by muse, mutect2, varscan2
- RYR1 | c.857C>A p.T286N | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62098872; called by muse, mutect2, varscan2
- SBF2 | c.3721G>T p.A1241S | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56300106; called by muse, mutect2, varscan2
- SEL1L | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.297); catalogued as COSV60920713; called by muse, mutect2
- SEMA4D | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV59395444, COSV59397805; called by muse, mutect2, varscan2
- SEMA6D | c.1871T>C p.F624S | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.083); catalogued as COSV60377878; called by muse, mutect2, varscan2
- SLC10A5 | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV72828380; called by muse, mutect2
- SLC12A2 | c.2632C>T p.R878C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs772690122, COSV52469337; called by muse, mutect2, varscan2
- SLC16A4 | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.462); catalogued as rs541251825, COSV63916624; called by muse, mutect2, varscan2
- SLC26A4 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV55917040; called by muse, mutect2
- SLC37A3 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.514); catalogued as rs573227005, COSV58265365; called by muse, mutect2, varscan2
- SMARCAL1 | c.2789C>T p.S930L | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV61921358; called by muse, mutect2
- SMURF1 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63157695; called by muse, mutect2, varscan2
- SON | c.3914T>C p.M1305T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as rs146846126; called by muse, mutect2, varscan2
- SPTA1 | c.3902T>G p.L1301R | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63754120; called by muse, mutect2, varscan2
- STK11 | c.88dup p.D30Gfs*133 | Frame Shift Ins (INS) | VAF 19/48 reads (40%) | catalogued as CI1414332; called by mutect2, pindel, varscan2
- STRN3 | c.1634G>C p.G545A (on ENST00000357479 / NM_001083893.2; = p.G461A on NM_014574.4) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62579937; called by muse, mutect2
- SYNE1 | c.11977C>A p.Q3993K (on ENST00000367255 / NM_182961.4; = p.Q3922K on NM_033071.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as COSV54996100; called by muse, mutect2, varscan2
- SYNE2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1297657206, COSV58360924; called by muse, mutect2, varscan2
- TAS2R16 | c.350G>A p.W117* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV50797187; called by muse, mutect2, varscan2
- TBC1D10B | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.224); catalogued as COSV69505113; called by muse, mutect2
- TECRL | c.744G>T p.R248S | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.265); catalogued as COSV67087434; called by muse, mutect2, varscan2
- TGFBR1 | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV66625396, COSV66625881; called by muse, mutect2, varscan2
- TJP3 | c.237G>C p.K79N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53662958; called by muse, mutect2, varscan2
- TMEM100 | c.178T>C p.F60L | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1227230634, COSV70118067; called by muse, mutect2, varscan2
- TMEM270 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57638783; called by muse, mutect2, varscan2
- TRPS1 | c.3748C>A p.H1250N (on ENST00000220888 / NM_001330599.2; = p.H1263N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV55242537, COSV99628582; called by muse, mutect2, varscan2
- UBXN7 | c.766G>C p.G256R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.727); catalogued as COSV56355741; called by muse, mutect2
- UNC5B | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58977551; called by muse, mutect2
- UNC93A | c.1311C>G p.I437M | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57807776; called by muse, mutect2, varscan2
- VSX1 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV65021635; called by muse, mutect2
- WWC1 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54651596; called by muse, mutect2, varscan2
- ZBTB24 | c.1702G>T p.G568C | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV57782210; called by muse, mutect2, varscan2
- ZFP30 | c.228G>A p.W76* | Nonsense Mutation (SNP) | VAF 34/240 reads (14%) | catalogued as COSV63622666; called by muse, mutect2, varscan2
- ZFYVE26 | c.2134A>T p.S712C | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV61329084; called by muse, mutect2, varscan2
- ZIK1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.629); catalogued as COSV56737287; called by muse, mutect2, varscan2
- ZNF232 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV51503550; called by muse, mutect2, varscan2
- ZNF33A | c.789C>G p.F263L (on ENST00000458705 / NM_006974.3; = p.F264L on NM_006954.2) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV56725326; called by muse, mutect2, varscan2
- ZNF436 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.363); catalogued as COSV58358628; called by muse, mutect2, varscan2
- ZNF521 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV64126181; called by muse, mutect2, varscan2
- CYP4B1 | c.43_44dup p.W16Cfs*6 | Frame Shift Ins (INS) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- FRG2C | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- IGHV4-59 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- IGHV5-51 | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAMA1 | c.6397C>T p.Q2133* | Nonsense Mutation (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- MYH1 | c.2592del p.E865Kfs*20 | Frame Shift Del (DEL) | VAF 39/138 reads (28%) | called by mutect2, pindel, varscan2
- NCOA7 | c.1473dup p.I492Yfs*24 | Frame Shift Ins (INS) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- SLC22A13 | c.396del p.R133Gfs*4 | Frame Shift Del (DEL) | VAF 21/123 reads (17%) | called by mutect2, pindel, varscan2
- SLC26A7 | c.705del p.L235Ffs*2 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- SYN2 | c.1143del p.D382Tfs*13 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- ADCY8 | c.1287C>A p.T429= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV53910055, COSV53928293; called by mutect2, varscan2
- ATG9A | c.252C>T p.V84= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs762494956, COSV60133351; called by muse, mutect2, varscan2
- BCL2 | c.606C>T p.Y202= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1434316861, COSV61381375; called by muse, mutect2, varscan2
- CDH1 | c.2173C>T p.L725= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as COSV55733574; called by muse, mutect2
- DNAH7 | c.7023G>T p.G2341= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs375086705; called by muse, mutect2, varscan2
- DOCK3 | c.5712C>T p.S1904= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV56524557; called by muse, mutect2, varscan2
- DRD3 | c.819A>T p.G273= | Silent (SNP) | VAF 42/182 reads (23%) | catalogued as COSV55680500; called by muse, mutect2, varscan2
- FRMPD2 | c.726G>A p.Q242= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV59718488; called by muse, mutect2
- GPR6 | c.1032C>T p.L344= | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as COSV51572139; called by muse, mutect2, varscan2
- GPR75 | c.1488C>T p.S496= | Silent (SNP) | VAF 53/223 reads (24%) | catalogued as COSV100765899; called by muse, mutect2, varscan2
- GRIN2B | c.1176C>A p.P392= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as rs1555112397, COSV74206081; ClinVar: likely benign; called by muse, mutect2, varscan2
- GUCY1B1 | c.27G>T p.L9= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV52376017; called by muse, mutect2, varscan2
- HK1 | c.1026C>T p.I342= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs567037782, COSV53859151; called by muse, mutect2, varscan2
- IDE | c.165C>T p.T55= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs755720607, COSV56423726; called by muse, mutect2, varscan2
- IGKV1-12 | c.129C>A p.I43= | Silent (SNP) | VAF 37/199 reads (19%) | catalogued as rs374869985; called by muse, mutect2, varscan2
- KLHL34 | c.69C>A p.R23= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as COSV65279323, COSV65279457; called by muse, mutect2, varscan2
- KRT1 | c.387T>C p.F129= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs553332826, COSV52867104; called by muse, mutect2
- LPIN3 | c.423G>A p.R141= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs1362479452, COSV64718558; called by muse, mutect2, varscan2
- LRP1 | c.3693C>G p.L1231= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV54513163; called by muse, mutect2
- MEPE | c.936T>C p.N312= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV63072940; called by muse, mutect2, varscan2
- MGAT4C | c.732A>T p.L244= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV59832024, COSV59833178; called by muse, mutect2, varscan2
- MRPL33 | c.126T>A p.T42= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs770493267, COSV56087983; called by muse, mutect2, varscan2
- MUC16 | c.26091T>A p.T8697= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV67469460; called by muse, mutect2, varscan2
- NDUFAF3 | c.315C>T p.F105= | Silent (SNP) | VAF 25/274 reads (9%) | catalogued as rs1405401961, COSV58245118; called by muse, mutect2
- OR4C3 | c.612C>A p.I204= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs762955826, COSV60586546; called by muse, mutect2, varscan2
- OR52L1 | c.9G>A p.L3= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs1482957997, COSV59987579; called by muse, mutect2, varscan2
- PCDH1 | c.231C>T p.L77= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs113157473, COSV54614458; called by muse, mutect2
- PDE1B | c.297C>T p.D99= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV54493239; called by muse, mutect2, varscan2
- PDZD7 | c.1272C>T p.L424= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs1231972142, COSV64646395; called by muse, mutect2
- PHLDB1 | c.3243G>T p.S1081= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as rs781835272, COSV100616344, COSV61878764; called by muse, mutect2, varscan2
- PIK3R6 | c.606G>T p.G202= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV61003463; called by muse, mutect2, varscan2
- POM121L12 | c.735C>T p.L245= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV101374895, COSV68693088; called by muse, mutect2, varscan2
- PRDM7 | c.229C>A p.R77= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV68322297, COSV68322905; called by muse, mutect2, varscan2
- PRKACB | c.444A>T p.A148= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV65759681; called by muse, mutect2, varscan2
- RPL23A | c.147G>A p.P49= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs781326437, COSV52644442, COSV52645202; called by muse, mutect2, varscan2
- RTP5 | c.867C>T p.L289= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as COSV58320283; called by muse, mutect2, varscan2
- SGIP1 | c.1398A>T p.P466= | Silent (SNP) | VAF 72/308 reads (23%) | catalogued as COSV52770142; called by muse, mutect2, varscan2
- SLC9C2 | c.135G>A p.L45= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV62946054; called by muse, mutect2, varscan2
- SYT4 | c.261G>A p.V87= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV54900851; called by muse, mutect2, varscan2
- TAAR1 | c.495C>T p.F165= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs1276935233, COSV51588723; called by muse, mutect2, varscan2
- TBC1D19 | c.1158G>A p.L386= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV53517237; called by muse, mutect2, varscan2
- TENM4 | c.6187C>T p.L2063= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs765332754, COSV53632800; called by muse, mutect2, varscan2
- TMEM38A | c.717C>T p.A239= | Silent (SNP) | VAF 89/431 reads (21%) | catalogued as COSV51819230; called by muse, mutect2, varscan2
- TRIM41 | c.1146C>T p.I382= | Silent (SNP) | VAF 30/272 reads (11%) | catalogued as COSV59319459; called by muse, mutect2, varscan2
- TSHZ3 | c.51C>T p.S17= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs780486345, COSV53672768; called by muse, mutect2, varscan2
- ZNF236 | c.4056G>T p.G1352= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV53486178, COSV53489333; called by muse, mutect2, varscan2
- ZNF423 | c.651C>G p.L217= (on ENST00000563137 / NM_001379286.1; = p.L209= on NM_015069.4) | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs761474474, COSV52190452; called by muse, mutect2, varscan2
- AC024940.1 | n.4218G>C | RNA (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- C1orf220 | n.606G>A | RNA (SNP) | VAF 15/82 reads (18%) | catalogued as rs998788168; called by muse, mutect2, varscan2
- GALNTL6 | c.-2C>A | 5'UTR (SNP) | VAF 10/24 reads (42%) | catalogued as COSV101550689; called by muse, mutect2, varscan2
- KRT18P55 | n.859C>G | RNA (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- LCN8 | c.93+525A>C | Intron (SNP) | VAF 15/38 reads (39%) | catalogued as COSV60210331; called by muse, mutect2, varscan2
- MIA2 | c.1887+35T>A | Intron (SNP) | VAF 24/75 reads (32%) | catalogued as COSV54483733; called by muse, mutect2, varscan2
- MIR1185-2 | n.49G>T | RNA (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- VNN3 | c.*341T>C | 3'UTR (SNP) | VAF 5/23 reads (22%) | catalogued as rs769113351, COSV99258006; called by muse, mutect2, varscan2
- WASF4P | n.1360G>C | RNA (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
